Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANZ, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANZ-01A (Primary Tumor).

Surgical Pathology Report

Patient Name:
Med. Rec. #:
DOB:
Gender:
Location:
Requestor:

Date Collected:
Date Received:
Date Reported:

Specimen(s) Received

Left testicle

Clinical History

Left testicular mass; LDH: 188, AFP: 1; HCG <2

Pre-Operative Diagnosis

R/O Malignancy

Gross Description

Received in formalin and labeled as Left testicle and consists of a testicle with attached spermatic cord which measures 13.5 x 4.5 x 3.5 cm. in total. The testicle measures 5.3 x 3.5 x 3.0 cm. The spermatic cord measures 9.0 cm. in length and varies in diameter from 1.5 cm. to 2.5 cm. There is a palpable mass protruding from the testicle. Serial sectioning reveals a firm, lobular, tan-yellow mass that measures 4.5 x 2.5 x 2.5 cm. This mass virtually replaces the entire normal testicle. The mass does not appear to invade through the tunica albuginea. Representative sections are submitted.

- 1 proximal spermatic cord
- 2 mid spermatic cord
- 3 distal spermatic cord with epididymis
- 4 tumor in relationship to vas deferens
- 5 tumor in relationship to rete testis
- 6-10 representative sections of tumor

Date of Dictation:

Gross Description by:

Microscopic Description

Performed.

Final Pathologic Diagnosis

Left testicle: Seminoma, Classic Type (4.5 x 2.5 x 2.5 cm.). No vascular or lymphatic invasion present. Tumor does not invade into tunica albuginea or rete testes. Spermatic cord margin free of tumor.

Pathologic Stage: pT1NXMXS0 (Stage I)

Attending Pathologist:

***Electronically Signed Out By

Source: NCI Genomic Data Commons file f958a59a-9971-419b-91a0-f2df9ebdc379 (TCGA-XE-AANZ-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).